Somatic mutation profile of tumor specimen TCGA-B0-5107-01A (aliquot TCGA-B0-5107-01A-01D-1421-08) from TCGA case TCGA-B0-5107, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 65.5 years (23,929 days).
Specimen TCGA-B0-5107-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4233572-14a1-488e-9b62-9e7877087655.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5107-11A (Solid Tissue Normal), aliquot TCGA-B0-5107-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4bdd6b8-485c-4e5d-a2d4-fe070949be1c

The open-access MAF lists 59 somatic variants for this specimen: 47 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 10, Nonsense Mutation 5, Frame Shift Del 5, Splice Site 3, Frame Shift Ins 1, Intron 1, Splice Region 1, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAP1 | c.850T>G p.Y284D | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56216524; called by muse, mutect2, varscan2
- ALPK3 | c.4291G>A p.G1431R | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750258262, COSV51938037; called by muse, mutect2, varscan2
- ANLN | c.2929A>C p.K977Q | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV56078611; called by muse, mutect2
- BAP1 | c.233A>G p.N78S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.608); catalogued as rs1319729011, CM160681, COSV56232513; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C3 | c.3594G>C p.Q1198H | Missense Mutation (SNP) | VAF 89/314 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV55578717, COSV55578945; called by muse, mutect2, varscan2
- CAPN3 | c.2013T>G p.D671E | Missense Mutation (SNP) | VAF 90/325 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV55520443; called by muse, mutect2, varscan2
- CCNT1 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 212/435 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV56065709; called by muse, mutect2, varscan2
- CHL1 | c.3380C>T p.S1127L (on ENST00000397491 / NM_001253387.1; = p.S1143L on NM_006614.4) | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.642); catalogued as COSV56602156; called by muse, mutect2, varscan2
- CIDEB | c.528-2A>G p.X176_splice | Splice Site (SNP) | VAF 21/47 reads (45%) | catalogued as COSV51867373; called by muse, mutect2, varscan2
- CPEB1 | c.587G>T p.G196V (on ENST00000617958; = p.G136V on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV55620760; called by muse, mutect2, varscan2
- CPXCR1 | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV52164094; called by muse, mutect2, varscan2
- CUZD1 | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs988668306, COSV59027638; called by muse, mutect2, varscan2
- CYP26B1 | c.1350C>A p.F450L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV50013731, COSV99134426; called by muse, mutect2, varscan2
- ECM1 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60874476; called by muse, mutect2, varscan2
- EVPL | c.2072G>A p.R691Q | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV56914550; called by muse, mutect2
- FBN3 | c.5119G>A p.A1707T | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.039); catalogued as COSV54469063; called by muse, mutect2, varscan2
- FGFBP1 | c.222G>T p.E74D | Missense Mutation (SNP) | VAF 86/269 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as COSV52587158; called by muse, mutect2, varscan2
- FLVCR2 | c.682A>G p.I228V | Missense Mutation (SNP) | VAF 126/282 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV53163975; called by muse, mutect2, varscan2
- JMY | c.2020C>A p.Q674K | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV68661028, COSV68661936; called by muse, mutect2, varscan2
- NEB | c.18911T>C p.I6304T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.438); catalogued as rs776955893, COSV51446217; called by muse, varscan2
- NHS | c.3319C>G p.P1107A | Missense Mutation (SNP) | VAF 85/295 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV66280295; called by muse, mutect2, varscan2
- NRF1 | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV56215427; called by muse, mutect2, varscan2
- OR1A1 | c.481C>A p.L161M | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100410814, COSV58404442; called by muse, mutect2, varscan2
- PBRM1 | c.996-2A>T p.X332_splice | Splice Site (SNP) | VAF 89/180 reads (49%) | catalogued as rs1360169168, COSV56268006, COSV99968412; called by mutect2, varscan2
- PHKA2 | c.253A>T p.M85L | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV66055596; called by muse, mutect2, varscan2
- POC1B | c.439del p.V147Yfs*12 | Frame Shift Del (DEL) | VAF 99/248 reads (40%) | catalogued as COSV100544091; called by mutect2, pindel, varscan2
- PPEF1 | c.1450C>T p.R484* | Nonsense Mutation (SNP) | VAF 54/175 reads (31%) | catalogued as COSV62996402; called by muse, mutect2, varscan2
- PRKDC | c.11414G>A p.W3805* | Nonsense Mutation (SNP) | VAF 15/102 reads (15%) | catalogued as COSV58060361; called by muse, mutect2, varscan2
- PRRC2A | c.3205G>A p.G1069R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV65688465; called by muse, mutect2, varscan2
- PTPRT | c.2075A>G p.N692S | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV62007844; called by muse, mutect2, varscan2
- RABGAP1 | c.3112G>A p.A1038T | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV65380760; called by muse, mutect2, varscan2
- RANBP2 | c.7148A>G p.N2383S | Missense Mutation (SNP) | VAF 253/897 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51703681; called by muse, mutect2, varscan2
- RBM14 | c.431T>G p.V144G | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59560256; called by muse, mutect2, varscan2
- RSPO1 | c.459G>A p.W153* | Nonsense Mutation (SNP) | VAF 40/163 reads (25%) | catalogued as COSV62975036; called by muse, mutect2, varscan2
- SHANK2 | c.3965C>G p.T1322S | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV53613538; called by muse, mutect2, varscan2
- SMARCA2 | c.3684+1G>A p.X1228_splice | Splice Site (SNP) | VAF 10/26 reads (38%) | catalogued as COSV61810985; called by muse, mutect2, varscan2
- SPAG17 | c.2628A>T p.K876N | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV60465076, COSV60469490; called by muse, mutect2, varscan2
- TLR8 | c.2386C>A p.P796T (on ENST00000218032 / NM_138636.5; = p.P814T on NM_016610.4) | Missense Mutation (SNP) | VAF 81/244 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54319784, COSV54321204; called by muse, mutect2, varscan2
- TXNDC12 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 45/163 reads (28%) | catalogued as COSV65406054; called by muse, mutect2, varscan2
- USP29 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 34/121 reads (28%) | catalogued as rs1254509485, COSV54144739, COSV54145537; called by muse, mutect2, varscan2
- WDR37 | c.960A>C p.T320= | Splice Region (SNP) | VAF 18/52 reads (35%) | catalogued as COSV54130918; called by muse, varscan2
- ZFPM2 | c.1580G>A p.R527Q | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1441226483, COSV65874746, COSV65875260; called by muse, mutect2, varscan2
- ARHGAP5 | c.701del p.N234Tfs*50 | Frame Shift Del (DEL) | VAF 90/251 reads (36%) | called by mutect2, pindel, varscan2
- ATR | c.3319del p.Y1107Ifs*12 | Frame Shift Del (DEL) | VAF 41/171 reads (24%) | called by mutect2, pindel, varscan2
- CUX1 | c.2786dup p.L930Afs*24 | Frame Shift Ins (INS) | VAF 39/153 reads (25%) | called by mutect2, pindel, varscan2
- GPX6 | c.43del p.L15Wfs*9 | Frame Shift Del (DEL) | VAF 19/96 reads (20%) | called by mutect2, pindel, varscan2
- NTN4 | c.141_142del p.W48Gfs*18 | Frame Shift Del (DEL) | VAF 45/139 reads (32%) | called by pindel, varscan2
- CRK | c.807T>C p.I269= | Silent (SNP) | VAF 51/187 reads (27%) | catalogued as COSV56031881; called by muse, mutect2, varscan2
- FCGBP | c.6549A>T p.S2183= | Silent (SNP) | VAF 44/298 reads (15%) | catalogued as rs992014140, COSV99661997; called by muse, mutect2, varscan2
- FCRLA | c.72C>A p.L24= (on ENST00000367959; = p.L7= on NM_032738.4) | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as COSV52687599; called by muse, mutect2, varscan2
- LAMA1 | c.2313G>A p.Q771= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV67542333; called by muse, mutect2, varscan2
- MAB21L1 | c.903C>T p.N301= | Silent (SNP) | VAF 53/159 reads (33%) | catalogued as COSV59765829; called by muse, mutect2, varscan2
- NATD1 | c.141C>T p.Y47= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs755635937, COSV67541255; called by muse, mutect2, varscan2
- NVL | c.843C>T p.L281= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs1282917405, COSV55875127; called by muse, mutect2, varscan2
- RHPN2 | c.906T>C p.N302= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV54283076; called by muse, mutect2, varscan2
- TLR4 | c.984T>C p.Y328= (on ENST00000355622 / NM_138554.5; = p.Y288= on NM_003266.4) | Silent (SNP) | VAF 70/152 reads (46%) | catalogued as COSV62923970; called by muse, mutect2, varscan2
- TMEM242 | c.66T>C p.N22= | Silent (SNP) | VAF 120/461 reads (26%) | catalogued as COSV65654435; called by muse, mutect2, varscan2
- AC005863.1 | n.379G>C | RNA (SNP) | VAF 26/114 reads (23%) | catalogued as rs757416609; called by muse, varscan2
- DPP6 | c.627+21161C>A | Intron (SNP) | VAF 22/84 reads (26%) | catalogued as COSV100124902; called by muse, varscan2
